Somatic mutation profile of cancer-model specimen HCM-STAN-0627-C34-85A (3D Organoid, passage 4; aliquot HCM-STAN-0627-C34-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-STAN-0627-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,727 days).
Specimen HCM-STAN-0627-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cd8a7db-9eb4-417a-8c74-8b202b1eb9ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0627-C34-10A (Blood Derived Normal), aliquot HCM-STAN-0627-C34-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ac6bbb6-b5d1-4298-929d-387b5d59d501

The open-access MAF lists 351 somatic variants for this specimen: 260 protein-altering or splice-affecting, 72 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 232, Silent 72, Nonsense Mutation 13, Intron 9, Frame Shift Del 9, 3'UTR 4, Frame Shift Ins 3, 5'UTR 3, Splice Region 2, 5'Flank 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 410/410 reads (100%) | hotspot (GDC flag); catalogued as rs141798398, CM072935, COSV58687783, COSV58689693; ClinVar: pathogenic; called by muse, varscan2
- FBN1 | c.3778G>T p.E1260* | Nonsense Mutation (SNP) | VAF 237/524 reads (45%) | catalogued as rs1555398283, CM972806; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 288/622 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY7 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 250/529 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs562841900; called by muse, mutect2, varscan2
- ADRA1A | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 304/304 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370056; called by muse, mutect2, varscan2
- AKAP11 | c.3589C>T p.Q1197* | Nonsense Mutation (SNP) | VAF 287/592 reads (48%) | catalogued as rs781004648; called by muse, mutect2, varscan2
- ALDH1A2 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 191/421 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1484902253; called by muse, mutect2, varscan2
- ALDH1A3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 340/732 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1432494592; called by muse, varscan2
- ATP5F1C | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV59623121; called by muse, mutect2, varscan2
- BMP6 | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 227/517 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51666517; called by muse, mutect2
- C8A | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 254/496 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as COSV63483235; called by muse, mutect2, varscan2
- CAGE1 | c.2179G>T p.A727S (on ENST00000512086; = p.A591S on NM_205864.3) | Missense Mutation (SNP) | VAF 158/334 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV57077070; called by mutect2, varscan2
- CAPRIN2 | c.2098C>G p.Q700E | Missense Mutation (SNP) | VAF 184/1208 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.291); catalogued as COSV51829937; called by muse, mutect2, varscan2
- CD109 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 151/329 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV54648959; called by muse, mutect2, varscan2
- CFAP99 | c.259G>C p.E87Q (on ENST00000506607; = p.E572Q on NM_001193282.3) | Missense Mutation (SNP) | VAF 389/389 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as COSV72247048; called by muse, mutect2, varscan2
- CLU | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 181/181 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs543267224, COSV57066235; called by muse, mutect2, varscan2
- CNKSR2 | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 357/357 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54250742; called by muse, varscan2
- COL12A1 | c.5362C>G p.Q1788E | Missense Mutation (SNP) | VAF 177/424 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as COSV100486871; called by muse, mutect2, varscan2
- COL22A1 | c.4855C>T p.R1619W | Missense Mutation (SNP) | VAF 242/472 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755307992, COSV57325647; called by muse, varscan2
- COL4A2 | c.4954G>A p.A1652T | Missense Mutation (SNP) | VAF 344/648 reads (53%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.942); catalogued as rs763103910, COSV100847246, COSV64633658; called by muse, varscan2
- CSMD3 | c.2162G>A p.C721Y (on ENST00000297405 / NM_001363185.1; = p.C617Y on NM_052900.3) | Missense Mutation (SNP) | VAF 109/222 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52334742, COSV99836666; called by muse, mutect2, varscan2
- CUL3 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 650/650 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV52363848, COSV52372958; called by muse, mutect2, varscan2
- CXCR2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV59282035; called by muse, varscan2
- DNAH5 | c.2535G>T p.Q845H | Missense Mutation (SNP) | VAF 423/701 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs757277607; called by muse, mutect2, varscan2
- DZIP3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 139/704 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs368033775; called by muse, mutect2, varscan2
- EPHA6 | c.2387G>T p.R796I (on ENST00000389672 / NM_001080448.3; = p.R188I on NM_173655.4) | Missense Mutation (SNP) | VAF 472/648 reads (73%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.809); catalogued as COSV101064895, COSV67559861; called by muse, mutect2, varscan2
- ERMARD | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 205/442 reads (46%) | catalogued as COSV100824891, COSV64652273; called by muse, mutect2, varscan2
- EXOC6 | c.2240A>G p.Y747C | Missense Mutation (SNP) | VAF 189/413 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363932301; called by muse, mutect2, varscan2
- FAM83H | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 508/900 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1430530122, COSV66353552; called by muse, varscan2
- FLRT2 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 324/956 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as rs538772019, COSV58136450; called by muse, mutect2, varscan2
- FOXG1 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 616/980 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as CM147915; called by muse, varscan2
- GPRC6A | c.2744C>A p.S915Y | Missense Mutation (SNP) | VAF 160/340 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59955761; called by muse, mutect2, varscan2
- GRIN2A | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 228/489 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs1240144483; called by muse, mutect2, varscan2
- GRIN2B | c.2713G>T p.A905S | Missense Mutation (SNP) | VAF 1558/1559 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV74206378; called by muse, varscan2
- GRIN2B | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 1340/1346 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as rs1280718157; called by muse, varscan2
- IGSF21 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 286/574 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs201284891, COSV52124955, COSV99246413; called by muse, varscan2
- IQCA1 | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 437/442 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54505700; called by muse, mutect2, varscan2
- KL | c.2632G>A p.G878R | Missense Mutation (SNP) | VAF 436/436 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as rs199676672, COSV66309227; called by muse, varscan2
- KMT2D | c.3361G>C p.D1121H | Missense Mutation (SNP) | VAF 324/670 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV56440520; called by muse, varscan2
- KNL1 | c.5872G>A p.E1958K (on ENST00000346991 / NM_170589.5; = p.E1932K on NM_144508.5) | Missense Mutation (SNP) | VAF 129/251 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61159031; called by muse, mutect2, varscan2
- KRIT1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 253/1710 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1480771068, COSV60670506; called by muse, mutect2, varscan2
- L3MBTL1 | c.1711-1G>T p.X571_splice (on ENST00000418998 / NM_001377303.1; = p.X481_splice on NM_015478.7) | Splice Site (SNP) | VAF 196/403 reads (49%) | catalogued as rs1159705449; called by muse, mutect2, varscan2
- LAMA1 | c.5796G>T p.L1932= | Splice Region (SNP) | VAF 222/409 reads (54%) | catalogued as rs1203740341; called by muse, mutect2
- LAP3 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 280/280 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV56898101; called by muse, mutect2, varscan2
- LATS1 | c.2589G>C p.Q863H | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1283487068; called by muse, varscan2
- LRRCC1 | c.2320G>C p.A774P | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99066558; called by muse, mutect2, varscan2
- LRRTM4 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 468/469 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297645; called by muse, mutect2, varscan2
- MAGEC1 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 245/400 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV99595479; called by muse, varscan2
- MAP2 | c.1525G>C p.D509H | Missense Mutation (SNP) | VAF 458/472 reads (97%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV52298483, COSV52302766; called by muse, mutect2, varscan2
- MBLAC1 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 991/1260 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV53542929; called by muse, varscan2
- METTL26 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 296/571 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100037220; called by muse, varscan2
- MRPL55 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 334/650 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54342003; called by muse, mutect2, varscan2
- MS4A14 | c.650T>C p.L217S | Missense Mutation (SNP) | VAF 227/494 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.224); catalogued as rs370208539; called by muse, mutect2, varscan2
- MUC15 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 383/384 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55554945; called by muse, mutect2, varscan2
- MUC4 | c.8641C>G p.L2881V | Missense Mutation (SNP) | VAF 362/2924 reads (12%) | SIFT tolerated, low confidence (0.99); PolyPhen probably damaging (0.951); catalogued as COSV100204950, COSV100206726; called by muse, varscan2
- MYO9A | c.1786A>G p.I596V | Missense Mutation (SNP) | VAF 165/385 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1328861103; called by muse, mutect2, varscan2
- NCAM2 | c.196A>T p.R66W | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53108385; called by muse, varscan2
- NDRG4 | c.1015G>A p.E339K (on ENST00000570248 / NM_001378344.1; = p.E358K on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 263/544 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs918762728; called by muse, mutect2, varscan2
- NEXN | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 150/306 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1332725424; called by muse, mutect2, varscan2
- NLRP13 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 442/450 reads (98%) | SIFT tolerated (0.64); PolyPhen benign (0.186); catalogued as rs184435930, COSV99048659; called by muse, varscan2
- NLRP5 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 475/482 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993605597, COSV101173910; called by muse, mutect2, varscan2
- NTRK3 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 222/474 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374759890; called by muse, varscan2
- NUDT19 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 340/717 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs891378669; called by muse, varscan2
- OPRK1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 332/636 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55572641, COSV55572689; called by muse, varscan2
- OR10J1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 273/580 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs141763562; called by muse, varscan2
- OR4K17 | c.381T>A p.C127* | Nonsense Mutation (SNP) | VAF 332/523 reads (63%) | catalogued as COSV59649148; called by muse, mutect2, varscan2
- OR5B21 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 158/395 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); catalogued as rs992774321; called by muse, mutect2, varscan2
- OR5I1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 211/447 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV56885869; called by muse, mutect2, varscan2
- OR6B2 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 237/1030 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1410751797; called by muse, mutect2
- OR6N1 | c.907A>G p.R303G | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100625017; called by muse, mutect2, varscan2
- OR8K3 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 218/432 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV57130713, COSV57130774; called by muse, varscan2
- OTOA | c.3394G>A p.A1132T (on ENST00000286149; = p.A1118T on NM_144672.4) | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1461905781; called by muse, mutect2, varscan2
- PCDHB2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 315/637 reads (49%) | catalogued as COSV52032846; called by muse, mutect2, varscan2
- PDE6A | c.2049G>C p.K683N | Missense Mutation (SNP) | VAF 188/435 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV99678506; called by muse, mutect2, varscan2
- PIK3R5 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 270/546 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs757328494; called by muse, varscan2
- PIK3R6 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 242/436 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs1372719081; called by muse, mutect2, varscan2
- PIWIL1 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 273/633 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs750461577, COSV55343720; called by muse, mutect2, varscan2
- PIWIL1 | c.24A>C p.R8S | Missense Mutation (SNP) | VAF 277/639 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs971930535; called by muse, mutect2, varscan2
- PKD1L3 | c.4768G>A p.E1590K | Missense Mutation (SNP) | VAF 260/267 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs567546445; called by muse, varscan2
- PNLIPRP1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 233/519 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998634455; called by muse, mutect2, varscan2
- PRAMEF4 | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 256/784 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.888); catalogued as rs764822617; called by muse, varscan2
- PRUNE2 | c.6893C>T p.A2298V | Missense Mutation (SNP) | VAF 199/399 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV65038010; called by muse, varscan2
- RAPH1 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 580/591 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs931579112; called by mutect2, varscan2
- RASGRF1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 273/573 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV69183490; called by muse, mutect2, varscan2
- RFX3 | c.1931A>G p.Q644R | Missense Mutation (SNP) | VAF 74/432 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV56522709; called by muse, mutect2, varscan2
- RHBDF1 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 243/525 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV99032514; called by muse, mutect2, varscan2
- RHBDL1 | c.802C>T p.Q268* (on ENST00000219551 / NM_001318733.2; = p.Q203* on NM_001278720.2) | Nonsense Mutation (SNP) | VAF 314/666 reads (47%) | catalogued as rs1223788193; called by muse, varscan2
- RUBCNL | c.1651C>A p.Q551K | Missense Mutation (SNP) | VAF 349/350 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV59792576; called by muse, mutect2, varscan2
- RYR2 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 469/469 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1232224119, COSV63720247; called by muse, mutect2, varscan2
- RYR2 | c.9569G>A p.R3190Q | Missense Mutation (SNP) | VAF 131/368 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as rs369276868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAGE1 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 173/173 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV61015085; called by muse, mutect2, varscan2
- SAMD5 | c.203A>T p.N68I | Missense Mutation (SNP) | VAF 377/799 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs759678529; called by muse, mutect2, varscan2
- SCAMP1 | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100210360; called by muse, mutect2, varscan2
- SLC9A3R1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 283/590 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV52855015; called by muse, mutect2, varscan2
- SPIRE1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 17/616 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59152708; called by muse, mutect2
- SYNE1 | c.23953G>T p.A7985S (on ENST00000367255 / NM_182961.4; = p.A7914S on NM_033071.3) | Missense Mutation (SNP) | VAF 143/322 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563082229; called by muse, mutect2, varscan2
- TAF2 | c.1672C>G p.Q558E | Missense Mutation (SNP) | VAF 149/295 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.351); catalogued as rs971616240; called by muse, mutect2, varscan2
- TAS2R41 | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 334/335 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as COSV99065175; called by muse, varscan2
- TGIF2LX | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 289/289 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV52214313; called by muse, mutect2, varscan2
- THSD1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 333/333 reads (100%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV51630014; called by muse, mutect2, varscan2
- TOP3A | c.2288C>G p.S763C | Missense Mutation (SNP) | VAF 312/690 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as COSV58181892; called by muse, varscan2
- USH2A | c.293C>G p.T98S | Missense Mutation (SNP) | VAF 250/536 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV56424880; called by muse, mutect2, varscan2
- UTRN | c.3569A>G p.K1190R | Missense Mutation (SNP) | VAF 223/468 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV100839427; called by muse, mutect2, varscan2
- ZNF235 | c.30C>G p.F10L | Missense Mutation (SNP) | VAF 121/296 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1192693192; called by muse, mutect2, varscan2
- ZNF280A | c.900C>A p.C300* | Nonsense Mutation (SNP) | VAF 689/1087 reads (63%) | catalogued as COSV57481684; called by muse, mutect2, varscan2
- AASDH | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 305/324 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABCA12 | c.4651G>C p.E1551Q (on ENST00000272895 / NM_173076.3; = p.E1233Q on NM_015657.3) | Missense Mutation (SNP) | VAF 491/492 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AC005551.1 | c.278T>C p.L93S | Missense Mutation (SNP) | VAF 315/874 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADCY1 | c.1276G>C p.A426P | Missense Mutation (SNP) | VAF 227/232 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRB3 | c.1993C>G p.Q665E | Missense Mutation (SNP) | VAF 137/292 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ALDH1A3 | c.36G>T p.Q12H | Missense Mutation (SNP) | VAF 341/732 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.125); called by muse, varscan2
- ALPG | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 567/589 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- AMPD1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 245/523 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ANKRD36 | c.4411G>A p.A1471T | Missense Mutation (SNP) | VAF 446/511 reads (87%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.943); called by muse, varscan2
- AQP9 | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 156/373 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID1A | c.2776_2777dup p.G927Lfs*15 | Frame Shift Ins (INS) | VAF 226/590 reads (38%) | called by mutect2, pindel, varscan2
- ASIC2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 200/425 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATG12 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 183/377 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP6V1E1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 129/137 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ATP7A | c.609A>T p.K203N | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BAAT | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 340/732 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- BAHCC1 | c.3652A>G p.R1218G | Missense Mutation (SNP) | VAF 408/872 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, varscan2
- C10orf67 | c.1393C>G p.R465G | Missense Mutation (SNP) | VAF 237/504 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C10orf71 | c.3465del p.R1156Dfs*8 | Frame Shift Del (DEL) | VAF 256/732 reads (35%) | called by pindel, varscan2
- C4orf33 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 178/179 reads (99%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, varscan2
- CAPN3 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 229/468 reads (49%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CCDC168 | c.15392A>T p.K5131M | Missense Mutation (SNP) | VAF 536/536 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CCDC191 | c.2808A>T p.E936D | Missense Mutation (SNP) | VAF 136/576 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC7 | c.1454G>T p.S485I (on ENST00000639629 / NM_001321115.2; = p.R485I on NM_145023.6) | Missense Mutation (SNP) | VAF 166/331 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CCR3 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCT8 | c.587A>T p.H196L | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEACAM16 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 38/1037 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- CEP126 | c.2861G>C p.R954T | Missense Mutation (SNP) | VAF 167/178 reads (94%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHSY3 | c.1632A>T p.L544F | Missense Mutation (SNP) | VAF 249/523 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CLOCK | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 205/205 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- CLUH | c.455A>G p.D152G (on ENST00000435359; = p.D190G on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 248/680 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- COG5 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 282/447 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- COL3A1 | c.1582G>T p.G528C | Missense Mutation (SNP) | VAF 324/324 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 347/347 reads (100%) | called by muse, mutect2, varscan2
- CPNE8 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 117/261 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CSMD3 | c.8027C>A p.S2676* (on ENST00000297405 / NM_001363185.1; = p.S2572* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 217/414 reads (52%) | called by muse, mutect2, varscan2
- CSMD3 | c.5624C>G p.S1875C (on ENST00000297405 / NM_001363185.1; = p.S1771C on NM_052900.3) | Missense Mutation (SNP) | VAF 136/289 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CTSZ | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 358/759 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUBN | c.5258G>A p.G1753D | Missense Mutation (SNP) | VAF 230/473 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CXorf21 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 300/300 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX60 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 249/250 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX32 | c.1775T>A p.L592* | Nonsense Mutation (SNP) | VAF 281/583 reads (48%) | called by mutect2, varscan2
- DNPEP | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 17/629 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EBF1 | c.912G>T p.L304F | Missense Mutation (SNP) | VAF 172/347 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ECD | c.21dup p.A8Cfs*17 | Frame Shift Ins (INS) | VAF 186/469 reads (40%) | called by mutect2, pindel, varscan2
- ECM2 | c.1311A>T p.L437F | Missense Mutation (SNP) | VAF 138/291 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- EGLN1 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 284/607 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ENPEP | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 311/311 reads (100%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, varscan2
- EPS15 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 183/386 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ERI3 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 294/627 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, varscan2
- FAM236C | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 158/196 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, varscan2
- FBXL16 | c.737C>G p.S246W | Missense Mutation (SNP) | VAF 398/822 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, varscan2
- FBXO30 | c.1584A>T p.R528S | Missense Mutation (SNP) | VAF 236/424 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- FGF13 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); called by muse, varscan2
- FHOD3 | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 332/334 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, varscan2
- FLG | c.9557C>G p.S3186C | Missense Mutation (SNP) | VAF 311/681 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- FN1 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMD6 | c.1145C>G p.S382C (on ENST00000344768 / NM_001267046.2; = p.S374C on NM_152330.4) | Missense Mutation (SNP) | VAF 306/834 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- GRHL3 | c.818C>T p.A273V (on ENST00000350501 / NM_198174.3; = p.A278V on NM_021180.3) | Missense Mutation (SNP) | VAF 219/500 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GRM6 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 212/474 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- GRPR | c.613del p.L205Ffs*33 | Frame Shift Del (DEL) | VAF 340/468 reads (73%) | called by mutect2, pindel, varscan2
- HDGFL2 | c.805T>C p.S269P | Missense Mutation (SNP) | VAF 634/641 reads (99%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); called by muse, varscan2
- HS3ST5 | c.548G>T p.R183M | Missense Mutation (SNP) | VAF 256/544 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- HSD3B2 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 298/644 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- HTR3A | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 151/151 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.701); called by muse, varscan2
- INSC | c.953dup p.E319Gfs*25 | Frame Shift Ins (INS) | VAF 168/450 reads (37%) | called by mutect2, pindel, varscan2
- INTS4 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 222/2880 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ITGAX | c.2986C>A p.L996I | Missense Mutation (SNP) | VAF 212/432 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- JAK2 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF13B | c.2533G>T p.G845W | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, varscan2
- KIF4B | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 406/835 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.2872G>C p.E958Q | Missense Mutation (SNP) | VAF 284/597 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP10-6 | c.412C>G p.Q138E | Missense Mutation (SNP) | VAF 582/826 reads (70%) | SIFT tolerated (0.24); PolyPhen benign (0.281); called by muse, varscan2
- LARP1 | c.1490C>G p.S497C (on ENST00000518297 / NM_033551.3; = p.S420C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 308/652 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LDLRAD4 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 409/858 reads (48%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMBRD1 | c.667A>G p.T223A (on ENST00000649011; = p.T201A on NM_018368.4) | Missense Mutation (SNP) | VAF 171/370 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- MADD | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 360/747 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MCM6 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 373/380 reads (98%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MEGF10 | c.1345G>C p.G449R | Missense Mutation (SNP) | VAF 195/402 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MERTK | c.1452T>C p.G484= | Splice Region (SNP) | VAF 354/355 reads (100%) | called by muse, varscan2
- METTL21A | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 417/417 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MGAT4B | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 246/560 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MT1HL1 | c.107G>C p.C36S | Missense Mutation (SNP) | VAF 340/728 reads (47%) | SIFT deleterious (0.02); called by muse, varscan2
- MUC4 | c.10247C>T p.S3416L | Missense Mutation (SNP) | VAF 340/3242 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); called by muse, varscan2
- MYLK | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 908/1244 reads (73%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, varscan2
- NBEA | c.7476C>A p.C2492* | Nonsense Mutation (SNP) | VAF 344/344 reads (100%) | called by muse, mutect2, varscan2
- NCOA2 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 221/477 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NEK6 | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 331/708 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIPAL4 | c.499T>C p.W167R | Missense Mutation (SNP) | VAF 178/328 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1AP | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 398/398 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS2 | c.2275T>C p.C759R | Missense Mutation (SNP) | VAF 124/542 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NSFL1C | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 276/574 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- NUP153 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 271/531 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.17026G>A p.E5676K | Missense Mutation (SNP) | VAF 252/550 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OGFRL1 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 315/642 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR2L8 | c.403A>T p.M135L | Missense Mutation (SNP) | VAF 233/928 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, varscan2
- OR2M2 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 631/632 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR4A47 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 236/537 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4A5 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 203/455 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); called by muse, varscan2
- OR4D2 | c.360del p.F120Lfs*17 | Frame Shift Del (DEL) | VAF 293/810 reads (36%) | called by pindel, varscan2
- OR4N2 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 275/1059 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.034); called by mutect2, varscan2
- OR51D1 | c.128del p.P43Hfs*14 | Frame Shift Del (DEL) | VAF 264/797 reads (33%) | called by pindel, varscan2
- OXLD1 | c.37_46del p.V13Rfs*47 | Frame Shift Del (DEL) | VAF 438/1041 reads (42%) | called by mutect2, pindel, varscan2
- PEX5L | c.1583T>C p.V528A | Missense Mutation (SNP) | VAF 265/858 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3C2B | c.3034C>T p.P1012S | Missense Mutation (SNP) | VAF 488/488 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.313); called by muse, varscan2
- PKHD1L1 | c.6625G>T p.D2209Y | Missense Mutation (SNP) | VAF 123/294 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLPPR4 | c.1489C>G p.P497A | Missense Mutation (SNP) | VAF 320/671 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- PPFIA1 | c.3503C>G p.S1168C | Missense Mutation (SNP) | VAF 450/4474 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- PPP2R3A | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 190/770 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PRLHR | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 225/485 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PTPRB | c.4745G>C p.R1582P | Missense Mutation (SNP) | VAF 175/396 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF150 | c.616del p.R206Afs*14 | Frame Shift Del (DEL) | VAF 198/333 reads (59%) | called by pindel, varscan2
- RSAD2 | c.283A>C p.K95Q | Missense Mutation (SNP) | VAF 17/476 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- S100A12 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 215/513 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SATB2 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SGK1 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 201/456 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGPP1 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 576/921 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLC6A14 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA33 | c.58A>T p.T20S | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, varscan2
- SPEN | c.3260G>C p.R1087T | Missense Mutation (SNP) | VAF 50/706 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2
- SSX5 | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 300/300 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ST8SIA6 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 154/345 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- STXBP4 | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 143/337 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- SYT2 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 268/581 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- TECPR2 | c.2354G>T p.R785L | Missense Mutation (SNP) | VAF 333/516 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TINAG | c.350del p.P117Qfs*16 | Frame Shift Del (DEL) | VAF 159/369 reads (43%) | called by mutect2, pindel, varscan2
- TRAFD1 | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 159/355 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TRAV12-3 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 236/388 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TRIM77 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, varscan2
- TRIOBP | c.5018del p.P1673Qfs*48 | Frame Shift Del (DEL) | VAF 308/789 reads (39%) | called by mutect2, pindel, varscan2
- TRPM1 | c.2686C>G p.Q896E | Missense Mutation (SNP) | VAF 304/616 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TTN | c.48952G>A p.D16318N (on ENST00000591111; = p.D8894N on NM_003319.4) | Missense Mutation (SNP) | VAF 197/203 reads (97%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.37167A>T p.Q12389H (on ENST00000591111; = p.Q4965H on NM_003319.4) | Missense Mutation (SNP) | VAF 355/355 reads (100%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTYH1 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 463/469 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- UBR2 | c.4331T>C p.I1444T | Missense Mutation (SNP) | VAF 80/519 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UBR4 | c.14467C>A p.L4823I | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- UBXN11 | c.812C>T p.S271L (on ENST00000374221 / NM_183008.2; = p.S238L on NM_145345.2) | Missense Mutation (SNP) | VAF 244/512 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USH2A | c.9011A>G p.H3004R | Missense Mutation (SNP) | VAF 210/417 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- USP40 | c.2854C>T p.Q952* | Nonsense Mutation (SNP) | VAF 499/500 reads (100%) | called by muse, varscan2
- USP9X | c.1924G>C p.V642L | Missense Mutation (SNP) | VAF 226/227 reads (100%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, varscan2
- VAV3 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 212/481 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- VPS13A | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13D | c.11031G>T p.E3677D | Missense Mutation (SNP) | VAF 246/496 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- VSIG10L | c.1941C>A p.D647E | Missense Mutation (SNP) | VAF 716/730 reads (98%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VWDE | c.80del p.G27Dfs*27 | Frame Shift Del (DEL) | VAF 178/303 reads (59%) | called by pindel, varscan2
- ZC3H12B | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 293/293 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFPM2 | c.2497A>T p.S833C | Missense Mutation (SNP) | VAF 288/607 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF154 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 235/531 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF208 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 284/286 reads (99%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.838); called by muse, varscan2
- ZNF280A | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 400/1286 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); called by muse, varscan2
- ZNF559 | c.879A>T p.R293S | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF569 | c.1671A>T p.K557N | Missense Mutation (SNP) | VAF 539/545 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF681 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 334/336 reads (99%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ZNF69 | c.1094G>C p.C365S | Missense Mutation (SNP) | VAF 214/504 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, varscan2
- ZNF888 | c.1607C>G p.S536C | Missense Mutation (SNP) | VAF 237/540 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ABCC12 | c.3522C>T p.A1174= | Silent (SNP) | VAF 223/467 reads (48%) | called by muse, varscan2
- ADAMTS19 | c.1881G>A p.K627= | Silent (SNP) | VAF 151/306 reads (49%) | catalogued as rs766354573; called by muse, varscan2
- ADGRG2 | c.1080C>T p.S360= (on ENST00000379869 / NM_001079858.3; = p.S357= on NM_005756.4) | Silent (SNP) | VAF 281/281 reads (100%) | catalogued as rs774854344; called by muse, mutect2, varscan2
- AP4B1 | c.654A>T p.V218= | Silent (SNP) | VAF 274/548 reads (50%) | called by muse, mutect2
- ATP13A2 | c.1125C>T p.F375= | Silent (SNP) | VAF 438/859 reads (51%) | catalogued as rs200948160; called by muse, mutect2, varscan2
- BTN1A1 | c.57C>T p.L19= | Silent (SNP) | VAF 180/430 reads (42%) | called by muse, varscan2
- CACNG3 | c.24C>T p.I8= | Silent (SNP) | VAF 185/388 reads (48%) | catalogued as rs777123441, COSV99135441, COSV99135533; called by muse, mutect2, varscan2
- CCDC151 | c.987A>G p.L329= | Silent (SNP) | VAF 516/518 reads (100%) | catalogued as rs1388624564, COSV62697445; called by muse, mutect2, varscan2
- CFAP46 | c.6876A>C p.T2292= | Silent (SNP) | VAF 154/310 reads (50%) | called by mutect2, varscan2
- CSNKA2IP | c.1734G>A p.A578= | Silent (SNP) | VAF 236/236 reads (100%) | catalogued as rs770127687; called by muse, varscan2
- DHX38 | c.1326C>T p.I442= | Silent (SNP) | VAF 266/272 reads (98%) | called by muse, mutect2, varscan2
- DNAAF4 | c.591T>C p.Y197= | Silent (SNP) | VAF 54/108 reads (50%) | catalogued as rs140091387; called by muse, mutect2, varscan2
- DNAH2 | c.996A>G p.A332= | Silent (SNP) | VAF 171/360 reads (48%) | called by muse, mutect2, varscan2
- DNAH5 | c.11793T>A p.P3931= | Silent (SNP) | VAF 188/598 reads (31%) | called by muse, mutect2, varscan2
- DPP6 | c.996C>T p.T332= (on ENST00000377770 / NM_001364500.2; = p.T270= on NM_001936.5) | Silent (SNP) | VAF 207/208 reads (100%) | catalogued as rs371237236; called by muse, varscan2
- DYNC2H1 | c.5985G>A p.A1995= | Silent (SNP) | VAF 288/288 reads (100%) | catalogued as rs771297555, COSV62094709; called by muse, varscan2
- F11R | c.747C>A p.L249= | Silent (SNP) | VAF 208/393 reads (53%) | called by muse, varscan2
- FAT3 | c.2637C>T p.I879= | Silent (SNP) | VAF 268/268 reads (100%) | catalogued as rs1565252211; called by muse, mutect2, varscan2
- FIGNL2 | c.1431C>T p.F477= | Silent (SNP) | VAF 435/815 reads (53%) | called by muse, mutect2, varscan2
- FRS2 | c.543A>G p.E181= | Silent (SNP) | VAF 164/327 reads (50%) | called by muse, varscan2
- GDF11 | c.553C>A p.R185= | Silent (SNP) | VAF 374/809 reads (46%) | catalogued as COSV99069998; called by muse, mutect2, varscan2
- GJB4 | c.75G>T p.L25= | Silent (SNP) | VAF 312/611 reads (51%) | called by muse, mutect2, varscan2
- GOSR1 | c.309C>T p.A103= | Silent (SNP) | VAF 184/402 reads (46%) | called by muse, mutect2, varscan2
- HTR1A | c.1137C>A p.T379= | Silent (SNP) | VAF 354/354 reads (100%) | called by muse, mutect2, varscan2
- HTR1B | c.18T>A p.A6= | Silent (SNP) | VAF 235/456 reads (52%) | called by muse, mutect2, varscan2
- INPPL1 | c.1962G>A p.E654= | Silent (SNP) | VAF 176/2441 reads (7%) | called by muse, mutect2
- IQSEC3 | c.234C>A p.A78= | Silent (SNP) | VAF 1804/2579 reads (70%) | called by muse, varscan2
- KCNAB1 | c.411T>C p.D137= (on ENST00000490337 / NM_172160.3; = p.D126= on NM_003471.3) | Silent (SNP) | VAF 351/561 reads (63%) | called by muse, mutect2, varscan2
- KLK1 | c.600C>T p.V200= | Silent (SNP) | VAF 192/429 reads (45%) | catalogued as rs754921741; called by muse, mutect2, varscan2
- LRRC15 | c.153G>A p.L51= | Silent (SNP) | VAF 372/1124 reads (33%) | catalogued as COSV61649841; called by muse, mutect2, varscan2
- LTC4S | c.372C>A p.L124= | Silent (SNP) | VAF 410/856 reads (48%) | called by muse, mutect2, varscan2
- MOCS3 | c.1155C>T p.S385= | Silent (SNP) | VAF 228/497 reads (46%) | catalogued as rs1312122100; called by muse, mutect2, varscan2
- MTX2 | c.9A>T p.L3= | Silent (SNP) | VAF 736/740 reads (99%) | called by muse, mutect2, varscan2
- NF1 | c.4671A>T p.T1557= (on ENST00000358273 / NM_001042492.3; = p.T1536= on NM_000267.3) | Silent (SNP) | VAF 239/498 reads (48%) | called by muse, mutect2, varscan2
- NOS2 | c.2094C>T p.Y698= | Silent (SNP) | VAF 276/536 reads (51%) | called by muse, mutect2, varscan2
- OLFM2 | c.264C>T p.R88= | Silent (SNP) | VAF 292/567 reads (51%) | catalogued as rs762562916, COSV53433460; called by muse, mutect2, varscan2
- OR11H12 | c.906C>T p.P302= | Silent (SNP) | VAF 232/859 reads (27%) | catalogued as rs1483811827; called by muse, mutect2, varscan2
- OR4F4 | c.564A>G p.L188= | Silent (SNP) | VAF 184/844 reads (22%) | called by muse, varscan2
- OR4N2 | c.330G>A p.G110= | Silent (SNP) | VAF 270/2263 reads (12%) | catalogued as rs746578363, COSV60052877; called by muse, mutect2, varscan2
- OR52K2 | c.429C>T p.I143= | Silent (SNP) | VAF 243/574 reads (42%) | called by muse, mutect2, varscan2
- OR8H3 | c.171C>T p.H57= | Silent (SNP) | VAF 272/588 reads (46%) | called by muse, varscan2
- PACSIN3 | c.261G>A p.A87= | Silent (SNP) | VAF 389/866 reads (45%) | catalogued as rs960798354, COSV54067455; called by muse, mutect2, varscan2
- PCDH15 | c.1731G>T p.R577= | Silent (SNP) | VAF 242/484 reads (50%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1713T>A p.G571= | Silent (SNP) | VAF 446/938 reads (48%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1185G>T p.P395= | Silent (SNP) | VAF 226/490 reads (46%) | catalogued as rs781836475, COSV53389869; called by muse, varscan2
- PKHD1L1 | c.6624G>T p.L2208= | Silent (SNP) | VAF 122/297 reads (41%) | called by muse, varscan2
- PLEKHG3 | c.2373C>T p.F791= (on ENST00000394691; = p.F847= on NM_001308147.2) | Silent (SNP) | VAF 702/1037 reads (68%) | called by muse, varscan2
- PNLIPRP1 | c.432C>A p.G144= | Silent (SNP) | VAF 234/515 reads (45%) | catalogued as COSV62612896; called by muse, mutect2, varscan2
- PNPLA5 | c.66C>A p.A22= | Silent (SNP) | VAF 540/1024 reads (53%) | catalogued as rs1317093021; called by muse, mutect2
- POM121L2 | c.1029A>T p.A343= | Silent (SNP) | VAF 244/485 reads (50%) | called by muse, mutect2, varscan2
- PRLR | c.807G>T p.P269= | Silent (SNP) | VAF 139/504 reads (28%) | catalogued as rs200768734, COSV51494007; called by muse, mutect2, varscan2
- RASIP1 | c.2664C>G p.P888= | Silent (SNP) | VAF 576/581 reads (99%) | called by muse, mutect2, varscan2
- REPS2 | c.459A>G p.P153= | Silent (SNP) | VAF 310/310 reads (100%) | called by muse, mutect2, varscan2
- RGS3 | c.3312G>A p.L1104= (on ENST00000350696 / NM_001282923.2; = p.L823= on NM_130795.4) | Silent (SNP) | VAF 311/633 reads (49%) | called by muse, mutect2, varscan2
- RGS8 | c.528G>A p.Q176= (on ENST00000367556 / NM_001369564.2; = p.Q194= on NM_033345.3) | Silent (SNP) | VAF 172/376 reads (46%) | called by muse, varscan2
- RNF213 | c.3705C>G p.L1235= | Silent (SNP) | VAF 308/687 reads (45%) | called by muse, mutect2, varscan2
- RTN2 | c.1086A>G p.T362= | Silent (SNP) | VAF 46/793 reads (6%) | called by muse, mutect2
- SALL1 | c.2436C>A p.S812= | Silent (SNP) | VAF 239/537 reads (45%) | catalogued as rs749605203; called by muse, varscan2
- SCAI | c.255G>A p.K85= (on ENST00000336505 / NM_001144877.3; = p.K108= on NM_173690.5) | Silent (SNP) | VAF 157/388 reads (40%) | called by muse, mutect2, varscan2
- SLC5A11 | c.252C>T p.F84= | Silent (SNP) | VAF 241/512 reads (47%) | catalogued as COSV61743066; called by muse, mutect2, varscan2
- SMG7 | c.1995G>A p.P665= | Silent (SNP) | VAF 412/412 reads (100%) | catalogued as rs561881733; called by muse, mutect2, varscan2
- SNX12 | c.210G>A p.R70= | Silent (SNP) | VAF 218/218 reads (100%) | called by muse, mutect2, varscan2
- SOX11 | c.954C>A p.I318= | Silent (SNP) | VAF 684/687 reads (100%) | called by muse, varscan2
- ST6GALNAC3 | c.723C>A p.T241= | Silent (SNP) | VAF 204/450 reads (45%) | catalogued as rs767948772, COSV60322540; called by muse, mutect2, varscan2
- TENT4A | c.642G>C p.G214= | Silent (SNP) | VAF 398/1279 reads (31%) | called by muse, varscan2
- THEMIS | c.606T>A p.L202= | Silent (SNP) | VAF 261/519 reads (50%) | called by muse, mutect2, varscan2
- TP53BP2 | c.2571A>G p.P857= (on ENST00000343537 / NM_001031685.3; = p.P728= on NM_005426.2) | Silent (SNP) | VAF 565/567 reads (100%) | called by muse, mutect2, varscan2
- TRPM1 | c.747C>T p.L249= | Silent (SNP) | VAF 351/746 reads (47%) | catalogued as rs1363786243; called by muse, mutect2, varscan2
- TSPYL5 | c.471G>T p.G157= | Silent (SNP) | VAF 463/915 reads (51%) | called by muse, mutect2, varscan2
- ULK4 | c.2418C>G p.L806= | Silent (SNP) | VAF 324/331 reads (98%) | catalogued as COSV100094945; called by muse, mutect2
- VCAN | c.2895T>G p.T965= | Silent (SNP) | VAF 200/200 reads (100%) | catalogued as rs141161041; called by muse, varscan2
- ZFP69B | c.1455G>A p.R485= | Silent (SNP) | VAF 274/586 reads (47%) | called by muse, varscan2
- BRD2 | c.-945G>T | 5'UTR (SNP) | VAF 161/349 reads (46%) | called by muse, mutect2, varscan2
- C16orf71 | c.276+18G>C | Intron (SNP) | VAF 352/712 reads (49%) | called by muse, varscan2
- CPLANE1 | c.*2266C>G | 3'UTR (SNP) | VAF 183/632 reads (29%) | catalogued as COSV57056422; called by muse, mutect2, varscan2
- DDX41 | c.*267C>T | 3'UTR (SNP) | VAF 338/644 reads (52%) | called by muse, mutect2, varscan2
- EHMT1 | c.2382+1711C>G | Intron (SNP) | VAF 160/377 reads (42%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+23823G>T | Intron (SNP) | VAF 264/491 reads (54%) | called by muse, varscan2
- KIAA1958 | c.1172-27416A>G | Intron (SNP) | VAF 233/514 reads (45%) | called by muse, varscan2
- MASP1 | c.1303+5314C>A | Intron (SNP) | VAF 354/1031 reads (34%) | called by muse, mutect2, varscan2
- MGAM | c.4618+1900C>A | Intron (SNP) | VAF 224/241 reads (93%) | catalogued as rs771435947; called by muse, varscan2
- NFASC | c.2471-1391A>G | Intron (SNP) | VAF 57/794 reads (7%) | called by muse, mutect2
- NPR3 | chr5:32710717 G>A | 5'Flank (SNP) | VAF 194/597 reads (32%) | called by muse, mutect2, varscan2
- NRSN1 | c.190-4382A>T | Intron (SNP) | VAF 119/243 reads (49%) | called by muse, mutect2, varscan2
- OR1N2 | c.-30T>A | 5'UTR (SNP) | VAF 192/401 reads (48%) | catalogued as COSV65460290; called by muse, mutect2
- RIMBP2 | c.102+8190G>T | Intron (SNP) | VAF 224/468 reads (48%) | called by muse, varscan2
- RTL10 | c.*258G>T | 3'UTR (SNP) | VAF 350/350 reads (100%) | called by muse, varscan2
- SHOC2 | c.-164G>T | 5'UTR (SNP) | VAF 173/406 reads (43%) | called by muse, mutect2, varscan2
- SLC17A2 | c.*74dup | 3'UTR (INS) | VAF 225/548 reads (41%) | called by mutect2, pindel, varscan2
- SLITRK2 | chrX:145827784 C>A | 3'Flank (SNP) | VAF 193/193 reads (100%) | catalogued as COSV59428513; called by muse, mutect2, varscan2
- Z99774.2 | chr22:26671871 A>G | 5'Flank (SNP) | VAF 258/774 reads (33%) | called by muse, mutect2, varscan2
